CPTAC case C3L-06090 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3d6b543f-d0d4-4efe-b010-011e17602243

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1982; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 38.1 years (13,926 days); Year of diagnosis: 2020; Days to last known disease status: 1,423 days (3.9 years); Progression or recurrence: no; Days to last follow up: 1,423 days (3.9 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Stem Cell Transplantation, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 367 days (1.0 years); Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 837 days (2.3 years); Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 1,059 days (2.9 years); Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 1,423 days (3.9 years); Karnofsky performance status: 60; ECOG performance status: 2.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Cigarettes per day: 5; Alcohol history: Yes; Alcohol intensity: Non-Drinker.

Biospecimens (5 samples)
- Samples C3L-06090-50, C3L-06090-51, C3L-06090-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3L-06090-55: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample C3L-06090-57: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
